Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45X, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45X-01A (Primary Tumor).

[page 1 of 3]
DOB: :

Sex: M

Physician:

Accession:

Received:

Pathologist:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (E) ANTERIOR FLOOR OF MOUTH:
Bone, no tumor present. (See Comment)

ICD-0-3
carcinoma, squamous cell, nos 8070/3
Site: mouth, floor, nos C04.9
h
10/1/12

COMMENT:

This supplemental report is issued to aid as an additional diagnosis for the bone portion of the specimen. The previous diagnosis remains the same.

Entire report and diagnosis completed by:
Report released by:

SIGNATURE:

DIAGNOSIS

- (A) CONTENTS RIGHT SUPRAOMOHYOID NECK DISSECTION:
METASTATIC SQUAMOUS CELL CARCINOMA IN 3 OF 6 LEVEL I LYMPH NODES
AND 1 OF 2 LEVEL III LYMPH NODES.
Two level II, twelve level V and two submental triangle lymph nodes,
no tumor present.
Salivary gland with atrophy, fibrosis and chronic inflammation, no
tumor present.
- (B) GINGIVAL LABIAL MARGIN:
Squamous mucosa, no tumor present.
- (C) MUCOSAL TONGUE MARGIN:
Squamous mucosa, no tumor present.
- (D) DEEP TONGUE MARGIN:
Muscle and fibrous tissue, no tumor present.
- (E) ANTERIOR FLOOR OF MOUTH:
INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED,
MARGIN OF RESECTION FREE OF TUMOR.
- (F) TEETH:
Teeth (gross only).

[page 2 of 3]
DOB:

Sex: M

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) CONTENTS, RIGHT SUPRA OMOHYOID NECK DISSECTION - The specimen is received in five separate containers with designation as to different levels.

Level I consists of a fragment of tan-yellow grossly hemorrhagic fibroadipose tissue (5.6 x 4.2 x 1.1 cm). Dissection reveals an unremarkable tan lobulated submandibular gland (2.6 x 1.7 x 1.1 cm) as well as six possible lymph nodes (ranging from 0.6 x 0.4 x 0.3 cm to 1.2 x 0.9 x 0.7 cm).

The level II contents measure (3.6 x 3.4 x 0.8 cm). Dissection reveals two possible lymph nodes (0.6 x 0.4 x 0.4 cm and 1.3 x 0.7 x 0.5 cm).

The level III contents consist of a fragment of tan-yellow focally hemorrhagic fibroadipose tissue (2.1 x 1.7 x 0.7 cm). Dissection reveals two apparent lymph nodes (0.3 x 0.2 x 0.1 cm and 1.6 x 0.7 x 0.6 cm).

The level V contents consist of a fragment of tan-yellow grossly hemorrhagic fibroadipose tissue (6.8 x 2.1 x 0.6 cm). Dissection reveals 13 possible lymph nodes (ranging from 0.2 cm to 1.3 x 0.7 x 0.4 cm).

The specimen from the submental triangle consists of a fragment of tan-yellow grossly hemorrhagic fibroadipose tissue (3.0 x 2.8 x 0.6 cm). Dissection reveals two apparent lymph nodes (each 0.4 cm in diameter).

SECTION CODE: A1, submandibular gland, level I, representative section. A2, two level I lymph nodes. A3-A6, one bisected level I lymph node per cassette. A7, two level I and II lymph nodes. A8, one bisected level III lymph node. A9, one level III lymph node. A10, four level V lymph nodes. A11, nine level V lymph nodes. A12, two submental lymph nodes.

(B) GINGIVAL LABIAL MARGIN - A pink-tan linear tissue fragment (1.8 x 0.2 x 0.2 cm).

SECTION CODE: B, submitted in toto for frozen section.

*FS/DX: BENIGN SQUAMOUS MUCOSA.

(C) MUCOSAL TONGUE MARGIN - A fragment of tan-red mucosa (3.7 x 0.3 x 0.2 cm). Specimen is received on Telfa pad with designations as to the left and right ends of the specimen.

INK CODE: Black - tip of section.

SECTION CODE: C1, right half of specimen for frozen section examination; C2, left half of specimen for frozen section examination.

*FS/DX: BENIGN SQUAMOUS MUCOSA.

(D) DEEP TONGUE MARGIN - A fragment of red-purple soft tissue (0.7 x 0.4 x 0.3 cm). Entirely submitted for frozen section examination as D.

*FS/DX: BENIGN MUSCLE AND FIBROUS TISSUE; NO TUMOR PRESENT.

(E) ANTERIOR FLOOR OF MOUTH - A segment of mandible with overall measurements (5.0 x 4.0 x 2.5 cm). In the anterior aspect of the bone an ulcerated friable and soft lesion approximately (2.5 x 1.0 x 1.5 cm). The tumor appears to be eroding the upper bony portion and invading between teeth. No bony fracture is identified. Tumor appear to grossly confine within the surgical margin. Tumor is submitted entirely from E1-E10.

(F) TEETH - Received are 13 teeth, the smallest (1.7 x 0.6 x 0.3 cm), and the largest (2.0 x 1.0 x 0.9 cm). Also received are tooth fragments (3.0 x 1.5 x

[page 3 of 3]
DOB: _____ Sex: M
Physician: _____

Received: _____ Pathologist: _____ Accession: _____
Case type: Surgical History

0.6 cm) in aggregate. For gross description only. No sections taken.

SNOMED CODES
M-80703 T-53000

9/9/12

History Case Pathology Report
File under: Pathology

Page 3 of 3
History Case Pathology

Source: NCI Genomic Data Commons file e0164e48-fb5d-4024-b2a3-c89b853ab752 (TCGA-CV-A45X.3A612629-1B17-413A-936B-81FC9D04E2F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).